Gene-level copy-number profile of tumor specimen HCM-CSHL-0366-C50-86A from HCMI case HCM-CSHL-0366-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.9 years (17,140 days).
Specimen HCM-CSHL-0366-C50-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dfe241f9-7aff-4edb-8830-51e00a5222be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0366-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/606b4d07-e704-4fe3-95ef-1b98e1dbbb06

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,362; copy number 2: 32,306; copy number 3: 14,646; copy number 4: 6,349; copy number 5: 1,938; copy number 6: 400; copy number 7: 257; copy number 8: 53; copy number 9: 62.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,355,529–78,355,834, 1 gene (within-gene range 0–2): LSM3P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,700 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–157,887, 9 genes, copy number 6–7 (within-gene range 6–11): OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr1:40,863,914–47,704,029, 230 genes, copy number 5–7 (broad region; genes not listed).
- chr1:48,295,373–50,023,954, 11 genes, copy number 5 (within-gene range 4–5): SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1, AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1.
- chr1:49,691,262–55,324,691, 167 genes, copy number 5–6 (broad region; genes not listed).
- chr1:59,131,932–62,190,926, 28 genes, copy number 5–6: HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7.
- chr1:63,593,411–66,924,856, 45 genes, copy number 6–7 (within-gene range 3–8): PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1.
- chr1:70,144,805–70,439,851, 8 genes, copy number 6 (within-gene range 3–6): LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH.
- chr1:166,387,727–232,808,407, 1,257 genes, copy number 5–7 (broad region; genes not listed).
- chr1:233,327,724–233,448,781, 2 genes, copy number 5: MAP3K21, RNU4-77P.
- chr1:234,261,706–234,274,465, 2 genes, copy number 5 (within-gene range 4–5): AL122008.1, SLC35F3-AS1.
- chr1:234,356,704–234,479,179, 6 genes, copy number 5: AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1.
- chr1:235,366,353–235,520,685, 5 genes, copy number 5: AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14.
- chr1:236,215,101–248,937,043, 275 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:9,843,443–10,002,277, 4 genes, copy number 5: TAF1B, AC010969.2, AC010969.3, GRHL1.
- chr3:11,745–409,417, 7 genes, copy number 6: LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1.
- chr3:78,597,239–82,463,675, 24 genes, copy number 5: ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr3:83,937,045–90,261,708, 47 genes, copy number 5: SRRM1P2, LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr5:43,874,367–45,895,970, 16 genes, copy number 5: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:30,102,897–30,673,006, 35 genes, copy number 6: TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10, TRIM15, TRIM26, PAIP1P1, HCG17, TRIM26BP, HLA-L, AL662795.2, HCG18, TRIM39, TRIM39-RPP21, RPP21, HLA-N, AL662795.1, UBQLN1P1, MICC, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16.
- chr6:126,340,115–126,683,847, 6 genes, copy number 5: CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9.
- chr9:134,849,298–134,849,682, 3 genes, copy number 6: MIR3689C, MIR3689A, MIR3689D1.
- chr10:84,173,801–84,561,263, 11 genes, copy number 6: C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5.
- chr12:66,767–2,697,950, 53 genes, copy number 5–9 (within-gene range 3–9): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3.
- chr12:38,646,822–39,619,803, 11 genes, copy number 5: CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3.
- chr12:39,755,025–40,106,089, 3 genes, copy number 9 (within-gene range 4–10): SLC2A13, AC121336.1, RPL30P13.
- chr12:40,156,113–45,610,620, 72 genes, copy number 5–9 (broad region; genes not listed).
- chr12:46,004,038–46,876,784, 13 genes, copy number 5–7: AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.
- chr14:18,645,044–18,667,370, 3 genes, copy number 6: CR383656.8, CR383656.11, CR383656.3.
- chr14:19,324,708–19,714,332, 23 genes, copy number 5: AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512310.11, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8, AL512310.4, AL512310.5, AL512310.6, AL512310.9, AL512310.7, AL512310.2, ARHGAP42P4, AL512310.1, OR11H2.
- chr14:42,989,201–46,651,781, 40 genes, copy number 5–6: AL163153.1, TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:48,045,481–48,491,767, 6 genes, copy number 5: AL359212.1, AL358335.3, RNU6-297P, AL358335.2, AL358335.1, RPL18P1.
- chr14:49,552,633–49,913,760, 30 genes, copy number 5–6: RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP.
- chr14:66,212,810–68,730,218, 42 genes, copy number 5–6 (within-gene range 3–6): AL359232.1, AL157997.1, CCDC196, GPHN, AL133241.1, AL049835.1, FAM71D, SF3B4P1, MPP5, AL135978.1, ATP6V1D, Y_RNA, EIF2S1, PLEK2, MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1.
- chr14:70,698,698–72,566,530, 27 genes, copy number 5–6 (within-gene range 2–6): LINC01269, MAP3K9, AC004816.1, AC004816.2, AC004825.1, AC004825.2, PCNX1, AC004825.3, AC005230.1, GTF3AP2, PTTG4P, AC004817.3, AC004817.5, AC004817.2, AC004817.1, AC004817.4, AC005476.2, SIPA1L1, AC005476.1, SNORD56B, RN7SL683P, AC004974.1, AC004900.1, AC005993.1, RGS6, Y_RNA, AC004828.2.
- chr19:186,373–409,147, 10 genes, copy number 6–8: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C.
- chr19:31,149,979–34,093,310, 67 genes, copy number 5 (broad region; genes not listed).
- chr19:34,172,504–35,169,881, 54 genes, copy number 5: LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5.
- chr19:36,421,536–36,913,029, 20 genes, copy number 5 (within-gene range 4–5): AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA.
- chr19:55,591,376–55,617,269, 4 genes, copy number 5: FIZ1, ZNF524, ZNF865, AC008735.4.

Autosomal genes at a single copy (total copy number 1): 1,598. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
